Somatic mutation profile of tumor specimen 0DRE10 from CCDI case PBCGHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,536 days).
Specimen 0DRE10: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abda12e-3c5d-49b7-a0ce-376890321074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ad9022a-d43b-49ea-a273-3757bd2233bc

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Intron 4, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 196/345 reads (57%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 206/252 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ASAP3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as rs774990747, COSV60873604; called by muse, mutect2, varscan2
- CEACAM3 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1326779062; called by muse, mutect2
- FOCAD | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 260/315 reads (83%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs370908909; called by muse, mutect2, varscan2
- FYB2 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 48/810 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs368042852; called by muse, mutect2
- KRTAP16-1 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 286/634 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1038367491; called by mutect2, varscan2
- KRTAP6-2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 109/405 reads (27%) | PolyPhen benign (0.02); catalogued as rs113947796; called by muse, mutect2, varscan2
- OR7A10 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.309); catalogued as COSV50166736; called by muse, mutect2
- SCUBE1 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174496305, COSV62612783; called by muse, mutect2, varscan2
- TPTE | c.1457C>T p.P486L (on ENST00000618007 / NM_199261.4; = p.P468L on NM_199259.4) | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs1448069894; called by muse, mutect2, varscan2
- TRIP4 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs148350479; called by muse, mutect2, varscan2
- ARHGAP30 | c.3137C>T p.P1046L (on ENST00000368013 / NM_001025598.2; = p.P835L on NM_181720.3) | Missense Mutation (SNP) | VAF 55/475 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRISP2 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 68/784 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2
- EGFLAM | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 129/518 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KANK2 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 17/558 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRTAP16-1 | c.1486C>G p.P496A | Missense Mutation (SNP) | VAF 204/497 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.1); called by muse, mutect2
- KRTAP16-1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 252/554 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- OR4C16 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by mutect2, varscan2
- TMEM92 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 155/730 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ZIC2 | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KRTAP16-1 | c.576C>G p.V192= | Silent (SNP) | VAF 279/649 reads (43%) | called by muse, mutect2, varscan2
- MST1R | c.2862A>G p.P954= | Silent (SNP) | VAF 126/571 reads (22%) | catalogued as rs1471614060; called by muse, mutect2, varscan2
- PCNA | c.180C>T p.Y60= | Silent (SNP) | VAF 85/443 reads (19%) | called by muse, mutect2, varscan2
- RSBN1 | c.351C>T p.R117= | Silent (SNP) | VAF 61/321 reads (19%) | called by muse, mutect2, varscan2
- SCN10A | c.2286C>T p.R762= | Silent (SNP) | VAF 105/239 reads (44%) | catalogued as rs756582059, COSV71862313; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA6D | c.3021G>A p.A1007= (on ENST00000316364 / NM_153618.2; = p.A945= on NM_020858.2) | Silent (SNP) | VAF 148/272 reads (54%) | catalogued as rs141992262; called by muse, mutect2, varscan2
- ZNF891 | c.1290A>G p.K430= | Silent (SNP) | VAF 66/556 reads (12%) | called by muse, mutect2, varscan2
- BRICD5 | c.336+19G>T | Intron (SNP) | VAF 149/259 reads (58%) | called by muse, mutect2, varscan2
- DDX5 | c.44+205T>C | Intron (SNP) | VAF 78/216 reads (36%) | called by muse, mutect2
- ISCA1 | c.-29C>T | 5'UTR (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2, varscan2
- S100A10 | c.*18G>A | 3'UTR (SNP) | VAF 55/391 reads (14%) | catalogued as rs762941945; called by muse, mutect2, varscan2
- TRAPPC3 | c.423+51G>C | Intron (SNP) | VAF 34/212 reads (16%) | catalogued as rs528958836; called by muse, mutect2, varscan2
- ZNF584 | c.292+177C>T | Intron (SNP) | VAF 294/456 reads (64%) | catalogued as rs746327994, COSV100183464, COSV59723246; called by muse, mutect2, varscan2
